Surgical pathology report (de-identified scan), TCGA case TCGA-19-2619, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-2619-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS

A-C. LEFT FRONTAL LOBE OF BRAIN, INTRA-AXIAL LESION, BIOPSY AND REMOVAL:
-- GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

Note: The majority of the tumor demonstrates morphologic features consistent with "small cell variant of glioblastoma multiforme".

Electronically Signed Out By

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consult Diagnosis

Touch Imprint and Microscopic: High grade glioma.

Clinical History:

left brain lesion frontal intra axial

Specimens Submitted As:

A:ANTERIOR BRAIN TUMOR
B:BRAIN TUMOR
C:BRAIN TUMOR

Gross Description:

A: Received fresh, for intraoperative consultation, labelled with the patient's name, number and "anterior brain tumor", is a 0.8 x 0.4 x 0.3 cm tan-pink, soft tissue fragment. A frozen section and a touch prep is performed on the specimen. The remainder is submitted for permanents. The specimen is submitted entirely in two cassettes labelled FSA1 and A2.

B:Received in formalin labeled with the patient's name and number, and "A", are multiple irregular, pink-tan, soft cerebriform tissue fragments measuring in aggregate 2.5 x 1.8 x 0.35 cm. Submitted in toto in one cassette.

C:Received in formalin labeled with the patient's name and number, and "B", are multiple irregular, opaque white to pink-tan, soft, cerebriform tissue fragments measuring in aggregate 4.4 x 3.5 x 0.7 cm. Submitted in toto in three cassettes.

Source: NCI Genomic Data Commons file 2e24b0ba-418c-4d32-aa97-5d6fbfc6458c (TCGA-19-2619.260109E5-21E7-41D0-909A-85ADD469F968.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).